Somatic mutation profile of tumor specimen TCGA-FD-A6TI-01A (aliquot TCGA-FD-A6TI-01A-11D-A32B-08) from TCGA case TCGA-FD-A6TI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.6 years (26,874 days).
Specimen TCGA-FD-A6TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 426dc570-b3d4-49a2-94f6-720b62379670.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TI-10A (Blood Derived Normal), aliquot TCGA-FD-A6TI-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce4a1d81-3cbf-4283-a912-fa128297afd2

The open-access MAF lists 136 somatic variants for this specimen: 111 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 20, Splice Site 8, Frame Shift Del 4, In Frame Del 3, Splice Region 3, RNA 2, Intron 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 6/8 reads (75%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by mutect2, varscan2
- RHOA | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 80/173 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs11552757, COSV69041809, COSV69042766; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1085307556, COSV60805503; ClinVar: pathogenic; called by muse, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, varscan2
- TSC1 | c.1264-1G>A p.X422_splice | Splice Site (SNP) | VAF 24/36 reads (67%) | catalogued as rs1554816432, COSV100051608, COSV53768250; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12898C>T p.P4300S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV68950047; called by muse, mutect2, varscan2
- AC134980.2 | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100171840, COSV60908948; called by muse, mutect2, varscan2
- ADAM30 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.414); catalogued as COSV65561909; called by muse, mutect2, varscan2
- ADGRD1 | c.938C>A p.S313* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV55443294, COSV55443584, COSV99895751; called by muse, mutect2, varscan2
- AGT | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64184478; called by muse, mutect2, varscan2
- ALKBH3 | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765627435, COSV57025985; called by muse, mutect2, varscan2
- AMY2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100796508, COSV63716747; called by muse, mutect2, varscan2
- ANXA11 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745864099, COSV55418011; called by muse, mutect2, varscan2
- ARID1A | c.1351-1G>T p.X451_splice | Splice Site (SNP) | VAF 55/174 reads (32%) | catalogued as COSV61372395, COSV61376929, COSV61389944; called by muse, varscan2
- ARID1A | c.2879-1G>A p.X960_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61372173, COSV61380279; called by muse, mutect2, varscan2
- ATL1 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63297408; called by muse, mutect2, varscan2
- ATM | c.8578_8580del p.S2860del | In Frame Del (DEL) | VAF 39/175 reads (22%) | catalogued as rs786203976; ClinVar: uncertain significance; called by pindel, varscan2
- ATP13A4 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV55074018; called by muse, mutect2, varscan2
- BBOX1 | c.471C>A p.D157E | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752306091, COSV54193317; called by muse, mutect2, varscan2
- CAMK2G | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.783); catalogued as rs141619679, COSV59484831; called by muse, mutect2, varscan2
- CAMTA1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV57898542; called by muse, mutect2, varscan2
- CCAR2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs761013874, COSV52386201; called by muse, mutect2, varscan2
- CCDC141 | c.2507G>A p.R836H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141786551; called by muse, mutect2, varscan2
- CCT5 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV54725133; called by muse, mutect2, varscan2
- CLDN18 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.983); catalogued as rs369029508, COSV59304518; called by muse, mutect2, varscan2
- COL12A1 | c.7546T>C p.Y2516H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV59405191; called by muse, mutect2, varscan2
- COL21A1 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs377305296, COSV99777552; called by muse, mutect2, varscan2
- DCC | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs145416326, COSV59128591; called by muse, mutect2, varscan2
- DNAH9 | c.5840G>A p.R1947K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.447); catalogued as COSV52370949; called by muse, mutect2, varscan2
- ELF3 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100668618, COSV62839941; called by muse, mutect2, varscan2
- EMC10 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as COSV100618498; called by muse, mutect2
- FAM171A1 | c.2587G>A p.D863N | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.323); catalogued as COSV65313466; called by muse, mutect2, varscan2
- FASTKD1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.655); catalogued as COSV70007198; called by muse, mutect2, varscan2
- FBN1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs1566934700, COSV57327591; called by muse, mutect2, varscan2
- FZD3 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 104/169 reads (62%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); catalogued as rs148525792; called by muse, mutect2, varscan2
- ITGA8 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65234492; called by muse, mutect2, varscan2
- ITPR2 | c.3911G>A p.G1304D | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67274395; called by muse, mutect2, varscan2
- KALRN | c.1246A>G p.M416V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs747328303, COSV53776813; called by muse, mutect2, varscan2
- KALRN | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1278212375, COSV53776822; called by muse, mutect2, varscan2
- KCND2 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV58598933; called by muse, mutect2, varscan2
- KMT2B | c.2983A>T p.T995S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55867407; called by muse, mutect2, varscan2
- KNDC1 | c.1512C>T p.N504= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as rs755288859, COSV58839894; called by muse, mutect2, varscan2
- LRP1B | c.6541A>T p.T2181S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101260833, COSV67262699; called by muse, mutect2, varscan2
- MAP3K9 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751015012, COSV67122589; called by muse, mutect2, varscan2
- MBP | c.757G>A p.E253K (on ENST00000355994 / NM_001025101.2; = p.E135K on NM_002385.3) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1334171636, COSV62828890; called by muse, mutect2, varscan2
- MCAM | c.1160A>C p.E387A | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50655629; called by muse, mutect2, varscan2
- MDM4 | c.4A>T p.T2S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1382884218, COSV65798189; called by muse, mutect2, varscan2
- MKRN2 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1241993145, COSV50107696; called by muse, mutect2, varscan2
- NAA25 | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.24); catalogued as COSV55707948; called by muse, mutect2, varscan2
- NCAN | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1393603592, COSV53056780; called by muse, mutect2, varscan2
- NOTCH2 | c.2369A>G p.Y790C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.432); catalogued as rs782522898, COSV56690333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPBWR2 | c.162del p.I55Sfs*6 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | catalogued as COSV63900003; called by mutect2, pindel, varscan2
- NR1D2 | c.341A>C p.H114P | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56993344; called by muse, mutect2, varscan2
- OR13C9 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs1449453306, COSV52241779, COSV52243398; called by muse, mutect2, varscan2
- PCDH9 | c.1322C>A p.A441D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60581664; called by muse, mutect2, varscan2
- PCDHGA12 | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1251651638, COSV52764458; called by muse, mutect2, varscan2
- PEAR1 | c.2461A>G p.S821G | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765375257, COSV52774521; called by muse, mutect2, varscan2
- PIK3C3 | c.914C>G p.T305S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV56283416; called by muse, mutect2, varscan2
- PPP2R5D | c.1354A>T p.R452W | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55146224; called by muse, mutect2, varscan2
- PPP2R5D | c.1355G>T p.R452M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55146232; called by muse, mutect2, varscan2
- PRAG1 | c.2180A>G p.N727S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV58165601; called by muse, mutect2, varscan2
- PRAMEF12 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV63216350; called by muse, mutect2, varscan2
- PRAMEF14 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 116/402 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1312967079; called by muse, mutect2, varscan2
- PRDM10 | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs746200394, COSV58799758, COSV58804296; called by muse, mutect2, varscan2
- PRDM11 | c.1471G>A p.G491S (on ENST00000530656 / NM_001359633.1; = p.A457T on NM_001256695.1) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as COSV55442938; called by muse, mutect2, varscan2
- RASAL1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs760009413, COSV55654107; called by muse, mutect2, varscan2
- RBM27 | c.1279+1G>A p.X427_splice | Splice Site (SNP) | VAF 32/122 reads (26%) | catalogued as rs887659316, COSV54590676; called by muse, mutect2, varscan2
- SACS | c.3157C>A p.L1053I | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV66545674; called by muse, mutect2, varscan2
- SAMD9L | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV59083628; called by muse, mutect2, varscan2
- SCN5A | c.1198G>T p.G400W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61137888; called by muse, mutect2, varscan2
- SELENBP1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs879129779, COSV64374058; called by muse, mutect2, varscan2
- SEMG1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs377393231; called by muse, mutect2, varscan2
- SHMT2 | c.309G>A p.K103= | Splice Region (SNP) | VAF 9/27 reads (33%) | catalogued as COSV61075059; called by muse, mutect2, varscan2
- SIGLEC6 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs748673476, COSV58436405; called by muse, mutect2, varscan2
- SLC35B2 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs775493883, COSV51491354; called by muse, mutect2, varscan2
- SLC9A5 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs576356728, COSV55364336; called by muse, varscan2
- SOS1 | c.2687G>T p.R896L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV67677250; called by muse, mutect2
- SPATA18 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54649066; called by muse, mutect2, varscan2
- SPTAN1 | c.5343-6_5355del p.X1781_splice | Splice Site (DEL) | VAF 21/38 reads (55%) | catalogued as COSV63989292; called by mutect2, pindel, varscan2
- SYNE1 | c.16920G>T p.E5640D (on ENST00000367255 / NM_182961.4; = p.E5569D on NM_033071.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV55073495; called by muse, mutect2, varscan2
- SYNE1 | c.16352A>T p.K5451M (on ENST00000367255 / NM_182961.4; = p.K5380M on NM_033071.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55073526; called by muse, mutect2, varscan2
- TCP1 | c.1102A>G p.K368E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV58460183; called by muse, mutect2, varscan2
- TGFBR1 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV66625245, COSV66626664; called by muse, mutect2, varscan2
- THBS2 | c.2495G>T p.G832V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64681530; called by muse, mutect2, varscan2
- TMIGD3 | c.659T>A p.I220N (on ENST00000369717 / NM_001081976.2; = p.I301N on NM_020683.7) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV63163750; called by muse, mutect2, varscan2
- TOGARAM2 | c.3043C>T p.P1015S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1360036923, COSV65423403; called by muse, mutect2, varscan2
- TOMM70 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52524917; called by muse, mutect2
- TOMM70 | c.1063G>C p.V355L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV52524943; called by muse, mutect2
- TTN | c.63731C>T p.S21244L (on ENST00000591111; = p.S13820L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | PolyPhen benign (0.131); catalogued as rs376574861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.22990C>T p.R7664W (on ENST00000591111; = p.R6737W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | PolyPhen possibly damaging (0.9); catalogued as rs1227497572, COSV60158883; called by muse, mutect2, varscan2
- TTN | c.22564A>T p.S7522C (on ENST00000591111; = p.S6595C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | PolyPhen benign (0.206); catalogued as COSV60279504; called by muse, varscan2
- TWF1 | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100286090; called by muse, mutect2, varscan2
- TXNDC11 | c.2483C>T p.S828F (on ENST00000356957 / NM_001303447.2; = p.S801F on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV51602206; called by muse, mutect2, varscan2
- UTP20 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV55381087; called by muse, mutect2, varscan2
- WDR13 | c.1013-1G>A p.X338_splice | Splice Site (SNP) | VAF 13/16 reads (81%) | catalogued as COSV54333210; called by muse, mutect2, varscan2
- WWC1 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54653685; called by muse, mutect2, varscan2
- ZFYVE9 | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.36); catalogued as COSV55098500; called by muse, mutect2, varscan2
- ZNF596 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV57655122; called by muse, mutect2
- ZNF804A | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV56466649; called by muse, mutect2, varscan2
- AKAP9 | c.6754C>A p.Q2252K (on ENST00000359028; = p.Q2228K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- CALM1 | c.320_322del p.R107del | In Frame Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ELF3 | c.151_155del p.L51Gfs*39 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel*, varscan2
- GPAT3 | c.481del p.X161_splice | Splice Site (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- IGHG2 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- MON1B | c.295del p.D99Tfs*17 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- MRC1 | c.1983G>A p.K661= | Splice Region (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.175T>G p.W59G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM27 | c.60-2_69del p.X20_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- RPL10L | c.385del p.V129Sfs*20 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- TLK1 | c.900_917del p.G301_V306del | In Frame Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel
- BCL9 | c.2787G>A p.P929= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs202240134; called by muse, mutect2, varscan2
- CARD11 | c.501G>A p.T167= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs757881829, COSV62716578; called by muse, mutect2, varscan2
- CCDC136 | c.2583G>A p.Q861= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV52803642; called by muse, mutect2, varscan2
- CD1A | c.87C>A p.V29= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV56863808; called by muse, mutect2
- DCAF12L1 | c.681C>T p.F227= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs777172062, COSV64422262; called by muse, mutect2, varscan2
- DENND1B | c.1500G>A p.K500= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs754871541, COSV54156435; called by muse, mutect2, varscan2
- GBA3 | c.423C>T p.S141= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV101545524, COSV72437850; called by muse, mutect2, varscan2
- GLI2 | c.3186C>T p.D1062= (on ENST00000361492 / NM_001374353.1; = p.D1079= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs769533860, COSV58049393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDLBP | c.375C>T p.L125= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV60499924; called by muse, mutect2, varscan2
- HMCN1 | c.9108A>T p.I3036= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as COSV54932126; called by muse, mutect2, varscan2
- KIF22 | c.1803C>A p.A601= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV50717550; called by muse, varscan2
- LRRTM1 | c.387C>A p.P129= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV54445622; called by muse, mutect2, varscan2
- OR4D10 | c.534C>T p.Y178= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV73260186; called by muse, mutect2, varscan2
- OR4F6 | c.60G>A p.S20= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as rs375136130, COSV61026431; called by muse, mutect2, varscan2
- PAPPA2 | c.4851G>A p.Q1617= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as COSV62808758; called by muse, mutect2, varscan2
- PPP2R2C | c.813C>T p.P271= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV59447030; called by muse, mutect2, varscan2
- SDS | c.573C>T p.I191= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs146027909; called by muse, mutect2, varscan2
- SEC24C | c.2298C>T p.F766= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1390489156, COSV59544330; called by muse, mutect2, varscan2
- SLITRK5 | c.1785C>T p.P595= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as COSV61525462; called by muse, mutect2, varscan2
- TULP4 | c.2670C>A p.T890= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV65579692; called by muse, mutect2, varscan2
- CDH11 | c.1895-535C>T | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99218621; called by muse, mutect2
- DCHS2 | n.3431G>A | RNA (SNP) | VAF 37/117 reads (32%) | catalogued as rs1561039077, COSV59737206; called by muse, mutect2, varscan2
- MIR379 | n.2G>C | RNA (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- NSD3 | c.1855+865G>C | Intron (SNP) | VAF 20/35 reads (57%) | catalogued as COSV57621437; called by muse, mutect2, varscan2
- PIK3C2B | c.*167G>C | 3'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100916144; called by muse, mutect2, varscan2
